Gene-level copy-number profile of tumor specimen ALCH-B46E-TTP1-A from ALCHEMIST case ALCH-B46E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,266 days).
Specimen ALCH-B46E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ab746728-8737-4f3a-99cd-b8fb4493371c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B46E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/ab7f11f7-87d8-4c67-8cf4-1ceee2b821d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 14,731; copy number 2: 40,633; copy number 3: 2,911; copy number 4: 71; copy number 5: 4; copy number 7: 3; copy number 9: 3; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,009,936–1,026,898, 1 gene: FGFRL1.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr9:136,359,480–136,373,681, 2 genes (within-gene range 0–2): DNLZ, CARD9.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr15:25,201,323–25,211,877, 7 genes (within-gene range 0–1): SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr16:1,064,093–1,096,244, 4 genes: SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8.
- chr16:1,148,224–1,230,184, 8 genes: AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2.
- chr17:10,320,392–10,341,458, 1 gene (within-gene range 0–2): AC005291.1.
- chr17:81,035,122–81,117,432, 1 gene (within-gene range 0–1): BAIAP2.
- chr17:81,125,276–81,133,308, 4 genes (within-gene range 0–1): MIR657, MIR3065, MIR338, MIR1250.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,048,021–42,058,517, 1 gene, copy number 5: PKDCC.
- chr7:127,610,292–127,618,142, 1 gene, copy number 5: PAX4.
- chr17:63,745,255–63,776,351, 1 gene, copy number 7 (within-gene range 2–7): CCDC47.
- chr22:18,361,820–18,404,206, 3 genes, copy number 5–7: FAM230J, AC011718.1, PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene, copy number 7 (within-gene range 2–7): AC023490.2.
- chr22:18,615,581–18,653,617, 4 genes, copy number 9–25: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 13,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
